Somatic mutation profile of tumor specimen TCGA-12-0707-01A (aliquot TCGA-12-0707-01A-01W-0348-08) from TCGA case TCGA-12-0707, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 55.1 years (20,136 days).
Specimen TCGA-12-0707-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37d8ed32-ecbc-4c13-badb-75643f6ddf21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-0707-10A (Blood Derived Normal), aliquot TCGA-12-0707-10A-01W-0348-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c70b1e23-66db-46d3-9c94-33cf2acfbb5c

The open-access MAF lists 74 somatic variants for this specimen: 58 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 15, Nonsense Mutation 5, Splice Site 2, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP7B | c.1847G>A p.R616Q | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs752850609, CM992592, COSV54438671; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 83/214 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AHCYL2 | c.824-2A>G p.X275_splice | Splice Site (SNP) | VAF 48/180 reads (27%) | catalogued as COSV61487383; called by muse, mutect2, varscan2
- AP5M1 | c.601G>A p.G201R | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.744); catalogued as COSV55105371; called by muse, mutect2, varscan2
- ATF7IP2 | c.995T>A p.I332K | Missense Mutation (SNP) | VAF 80/204 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as COSV61093533; called by muse, mutect2, varscan2
- BBS9 | c.2411A>T p.D804V (on ENST00000242067 / NM_001348036.1; = p.D764V on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54168758; called by muse, varscan2
- BOLA3 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.054); catalogued as COSV54876767; called by muse, mutect2, varscan2
- BTBD11 | c.1261C>T p.R421C | Missense Mutation (SNP) | VAF 79/233 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs1305403349, COSV55021363; called by muse, mutect2, varscan2
- CAD | c.1430G>C p.G477A | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV53027099; called by muse, mutect2, varscan2
- CAMK2A | c.632C>G p.P211R | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV62246464; called by muse, mutect2, varscan2
- CCDC7 | c.3700G>T p.E1234* | Nonsense Mutation (SNP) | VAF 182/274 reads (66%) | catalogued as COSV100179306, COSV56542497; called by muse, mutect2, varscan2
- CHAF1A | c.1618G>A p.V540M | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as rs1035706521, COSV56672321; called by muse, mutect2, varscan2
- DAO | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 127/411 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140015394; called by muse, mutect2, varscan2
- DAOA | c.20G>A p.G7D | Missense Mutation (SNP) | VAF 107/231 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.301); catalogued as COSV61602485; called by muse, mutect2, varscan2
- DEPDC5 | c.2183G>A p.R728H (on ENST00000400246; = p.R797H on NM_014662.5) | Missense Mutation (SNP) | VAF 42/55 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56692966; called by muse, varscan2
- DRD1 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV67104633; called by muse, mutect2, varscan2
- DUOX2 | c.4442T>C p.F1481S | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66532249; called by muse, mutect2, varscan2
- EGFR | c.809A>G p.Y270C | Missense Mutation (SNP) | VAF 354/6004 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51781245; called by muse, mutect2
- EPHA8 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758018689, COSV51263200; called by muse, mutect2, varscan2
- FCGBP | c.11987G>A p.R3996H | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.057); catalogued as rs562548497; called by muse, mutect2, varscan2
- FLG | c.6439G>A p.G2147R | Missense Mutation (SNP) | VAF 49/553 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.031); catalogued as rs746864718, COSV100912335, COSV64238766, COSV64251212; called by muse, mutect2
- FLT1 | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 186/544 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56728426; called by muse, mutect2, varscan2
- GBGT1 | c.189-1G>A p.X63_splice | Splice Site (SNP) | VAF 9/17 reads (53%) | catalogued as COSV64404431; called by muse, mutect2, varscan2
- HNF4G | c.422A>T p.E141V (on ENST00000354370 / NM_001330561.2; = p.E188V on NM_004133.5) | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV100585085; called by muse, mutect2
- IARS1 | c.3388G>A p.A1130T | Missense Mutation (SNP) | VAF 162/266 reads (61%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs139893778, COSV65113087; called by muse, mutect2, varscan2
- JAML | c.104G>A p.G35D (on ENST00000356289 / NM_001098526.2; = p.G25D on NM_153206.3) | Missense Mutation (SNP) | VAF 111/303 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs755024063, COSV52627712; called by muse, mutect2, varscan2
- KRT82 | c.661G>T p.E221* | Nonsense Mutation (SNP) | VAF 26/88 reads (30%) | catalogued as COSV57786084; called by muse, mutect2, varscan2
- KRTAP10-8 | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 71/189 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs781898287, COSV58166373; called by muse, mutect2, varscan2
- LRRC8D | c.725G>A p.S242N | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV100487621; called by muse, mutect2, varscan2
- LUC7L3 | c.1177T>C p.S393P | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.91); catalogued as COSV53587122; called by muse, mutect2, varscan2
- MAN1C1 | c.1296dup p.L433Afs*67 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | catalogued as rs759630213; called by pindel, varscan2
- MYO5C | c.1471C>G p.Q491E | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99955634; called by muse, mutect2, varscan2
- NAV2 | c.3733T>A p.S1245T (on ENST00000396087 / NM_001244963.2; = p.S1222T on NM_145117.5) | Missense Mutation (SNP) | VAF 58/118 reads (49%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.633); catalogued as COSV60659552; called by muse, mutect2, varscan2
- NFE2L3 | c.880G>A p.G294S | Missense Mutation (SNP) | VAF 305/1166 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.07); catalogued as COSV50228649; called by muse, mutect2, varscan2
- NLRP3 | c.502C>T p.R168* | Nonsense Mutation (SNP) | VAF 63/132 reads (48%) | catalogued as rs746159202, COSV100275560, COSV60223782; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP7 | c.1008C>G p.H336Q | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60175025; called by muse, mutect2, varscan2
- NOS1 | c.2924G>A p.R975H | Missense Mutation (SNP) | VAF 348/819 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs561693400, COSV57612982, COSV57620960; called by muse, mutect2, varscan2
- NRAS | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 13/316 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.601); catalogued as COSV101056357, COSV65734657; called by muse, mutect2
- OR52R1 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 181/501 reads (36%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.94); catalogued as rs75386291, COSV61888911; called by muse, mutect2, varscan2
- PCDH11Y | c.3596C>T p.A1199V | Missense Mutation (SNP) | VAF 246/316 reads (78%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.487); catalogued as COSV99292977; called by muse, mutect2, varscan2
- PDK3 | c.685G>T p.D229Y | Missense Mutation (SNP) | VAF 136/190 reads (72%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV64793510; called by muse, mutect2, varscan2
- PEG3 | c.2574G>C p.K858N | Missense Mutation (SNP) | VAF 219/668 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1179001231, COSV55634290; called by muse, mutect2, varscan2
- PIWIL3 | c.1348C>T p.R450* | Nonsense Mutation (SNP) | VAF 83/244 reads (34%) | catalogued as rs201028643; called by muse, mutect2, varscan2
- PPP4R3B | c.2088A>G p.I696M (on ENST00000616407 / NM_001122964.3; = p.I611M on NM_020463.4) | Missense Mutation (SNP) | VAF 68/210 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.474); catalogued as rs1276668001, COSV55404806; called by muse, mutect2, varscan2
- PRDM9 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs373299038, COSV57006680; called by muse, mutect2, varscan2
- PTEN | c.530A>C p.Y177S | Missense Mutation (SNP) | VAF 236/355 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as CD983505, COSV64289389, COSV64289854, COSV64294530, COSV64297160; called by muse, mutect2, varscan2
- RNF145 | c.433C>G p.Q145E (on ENST00000424310 / NM_001199383.2; = p.Q173E on NM_144726.2) | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV50866564; called by muse, mutect2, varscan2
- S100A7 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 111/289 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs764601020, COSV64193332; called by muse, mutect2, varscan2
- SETD2 | c.7409G>T p.S2470I | Missense Mutation (SNP) | VAF 14/271 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.758); catalogued as COSV100340160; called by muse, mutect2
- SLC27A1 | c.607T>C p.F203L | Missense Mutation (SNP) | VAF 64/288 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as COSV53097558; called by muse, mutect2, varscan2
- SLC7A9 | c.1036G>A p.V346I | Missense Mutation (SNP) | VAF 64/207 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as rs780778962, COSV50085709; called by muse, mutect2, varscan2
- SLITRK4 | c.1040T>A p.F347Y | Missense Mutation (SNP) | VAF 79/108 reads (73%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV62024012; called by muse, mutect2, varscan2
- SMARCAL1 | c.25C>T p.Q9* | Nonsense Mutation (SNP) | VAF 111/407 reads (27%) | catalogued as COSV61921170; called by muse, mutect2, varscan2
- STAG3 | c.1513G>T p.A505S | Missense Mutation (SNP) | VAF 21/412 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.082); catalogued as COSV100426213; called by muse, mutect2
- TGFB1 | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs200230083, COSV55725009; called by muse, mutect2, varscan2
- TYW1 | c.910G>T p.D304Y | Missense Mutation (SNP) | VAF 49/195 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as COSV62752687; called by muse, mutect2, varscan2
- UMODL1 | c.2255C>T p.T752M (on ENST00000408910 / NM_001004416.2; = p.T880M on NM_173568.3) | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.353); catalogued as rs369805254; called by muse, varscan2
- H1-7 | c.728A>G p.K243R | Missense Mutation (SNP) | VAF 2/15 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.292); called by muse, mutect2
- ANKRD30A | c.864G>A p.A288= (on ENST00000611781; = p.A232= on NM_052997.2) | Silent (SNP) | VAF 25/38 reads (66%) | catalogued as rs369194109, COSV64602846, COSV64610666; called by muse, mutect2, varscan2
- CASZ1 | c.987C>T p.N329= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs377360245, COSV59735740; called by muse, mutect2, varscan2
- CD33 | c.10C>T p.L4= | Silent (SNP) | VAF 45/185 reads (24%) | catalogued as COSV51801942; called by muse, mutect2, varscan2
- CSMD3 | c.1203C>T p.L401= | Silent (SNP) | VAF 67/193 reads (35%) | catalogued as COSV52186262; called by muse, mutect2, varscan2
- EYA4 | c.867G>A p.T289= | Silent (SNP) | VAF 246/701 reads (35%) | catalogued as rs763899252, COSV62050744; called by muse, varscan2
- GRIA3 | c.1782A>G p.Q594= | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as COSV99992025; called by muse, mutect2
- KMT2A | c.9909A>G p.P3303= | Silent (SNP) | VAF 131/358 reads (37%) | catalogued as COSV63286005; called by muse, mutect2, varscan2
- LAMP5 | c.483G>A p.K161= | Silent (SNP) | VAF 62/206 reads (30%) | catalogued as COSV55716504; called by muse, mutect2, varscan2
- LCT | c.3603C>T p.A1201= | Silent (SNP) | VAF 88/292 reads (30%) | catalogued as rs759189427, COSV51549773; called by muse, mutect2, varscan2
- LGI3 | c.939G>A p.T313= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV60443431; called by muse, varscan2
- MAGEB4 | c.81T>A p.V27= | Silent (SNP) | VAF 31/37 reads (84%) | catalogued as COSV64397145; called by muse, mutect2, varscan2
- OR13C8 | c.450C>T p.V150= | Silent (SNP) | VAF 101/212 reads (48%) | catalogued as COSV58611219; called by muse, mutect2, varscan2
- SAP130 | c.2613G>A p.E871= | Silent (SNP) | VAF 442/1111 reads (40%) | catalogued as COSV52097446; called by muse, mutect2, varscan2
- SPTBN4 | c.3726T>C p.R1242= | Silent (SNP) | VAF 49/197 reads (25%) | catalogued as COSV58950003; called by muse, mutect2, varscan2
- TINAG | c.237G>A p.A79= | Silent (SNP) | VAF 950/2337 reads (41%) | catalogued as rs754542362, COSV52509759; called by muse, mutect2, varscan2
- EYA4 | c.1757-118G>A | Intron (SNP) | VAF 30/88 reads (34%) | catalogued as rs757084701, COSV100766002, COSV62052455; called by muse, mutect2, varscan2
